CCDI case PBBRJW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2d01d9ca-5832-4d5a-9738-2a39312deed0

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.2 years (5,925 days).

Biospecimens (3 samples)
- Sample 0DEV2F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEV3R: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEV4Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
